Surgical pathology report (de-identified scan), TCGA case TCGA-DU-6407, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-6407-02A (Recurrent Tumor).

[page 1 of 2]
Anatomic Pathology/Cytology Document State: (version)

Update Date/Time:
Final 1

Patient Name:

MRN:

Service Date/Time:

DOB/Age/Gender:

Female Provider:

Location: Responsible Staff:

ICD O3
Oligoastrocytoma, grade II
938213 NOS
Site Brain, supratentorial
C71.0
R Brain, temporal lobe
C71.2
JW 9/30/13

Surgical Pathology Report

Patient Name:

Accession #:

Med: Rec.:

Phone Number:

DOB:

Gender: F

Client:

Taken:

Received:

Reported:

Physician(s):

Phy Location:

CLINICAL HISTORY

The patient is a year-old woman with a history of oligodendroglioma (WHO grade II) resected in . At that time the reported Ki-67 labeling index of the tumor was 3%. She now presents with an MRI signal abnormality concerning for recurrent tumor.

OPERATIVE DIAGNOSES

Not Given

Operation/Specimen: A: Brain, right temporal excision biopsy

B: Brain, right temporal excision biopsy

PATHOLOGICAL DIAGNOSIS:

Brain, right temporal lesion, excisional biopsy: oligoastrocytoma (WHO grade II) (see comment).

COMMENT

The focally high proliferative index and strong diffuse p53 immunoreactivity may suggest aggressive clinical behavior and/or transition toward a higher grade lesion. Clinical correlation is recommended.

Electronically Signed Out

, Senior Staff Pathologist

PROCEDURES/ADDENDA

MGMT Promoter Methylation

Date Ordered:

Date Reported:

Interpretation

POSITIVE - Methylated MGMT promoter is detected

Results-Comments

Testing was done on block

(B1).

TEST DESCRIPTION: Bisulfite treatment of DNA followed by PCR amplification of both methylated and unmethylated MGMT promoter sequences, with products detected by gel electrophoresis.

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test was developed and its performance characteristics determined by the as required by CLIA '88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has

[page 2 of 2]
determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

Electronically Signed Out

, Senior Staff Pathologist

Consultant:

=====

INTRA-OPERATIVE CONSULTATION

A. Brain, right temporal lesion, excisional biopsy: infiltrating glioma (consistent with recurrent oligodendroglioma).

, Senior Staff Pathologist

GROSS DESCRIPTION

A. Received from the operating room are two fragments of soft tan tissue measuring approximately 0.9 x 0.8 x 0.4 cm in aggregate. Small samples are used for smear preparations and frozen sections. The frozen section remnant is submitted in cassette A1 and the unfrozen tissue is submitted in cassette A2.
B. Received from the operating room are two fragments of soft tan tissue measuring approximately 1.2 x 0.9 x 0.5 cm in aggregate. The samples are submitted in B1-B2.

, Resident Pathologist

MICROSCOPIC DESCRIPTION

Sections of A and B show an infiltrating glial neoplasm composed of cells with

mostly eccentrically placed round nuclei reminiscent of mini-gemistocytes. Other areas show similar cells with angulated nuclei and more astrocytic appearing morphology similar to conventional gemistocytes. Rare mitotic figures are noted and occasional apoptotic cells are seen. Necrosis and/or definite vascular proliferation are not identified. The tumor is strongly, diffusely p53 immunoreactive. The Ki-67 labeling index is approximately 5% overall and 15% in the most proliferative areas.

ICD-9(s):

239.6 239.6

Billing Fee Code(s):

A:

B:

MGMT:

Histo Data

Part A: Brain, right temporal excision biopsy

Taken: Received:

Stain/cnt Block Ordered Comment

H/E x 1 1

H/E x 1 2

Part B: Brain, right temporal excision biopsy

Taken: Received:

Stain/cnt Block Ordered Comment

H/E x 1 1

MGMT x 1 1

H/E x 1 2

MIB1-DA x 1 2

P53DO7 x 1 2

*** End of Report ***

HtPAA Discrepancy		✓

Source: NCI Genomic Data Commons file 187c029d-5a93-4034-b59c-c28ed702aaf3 (TCGA-DU-6407.C5AFC13B-06DA-471E-A59F-8F2E477D8B4D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).